Somatic mutation profile of tumor specimen 0DP48B from CCDI case PBCCXE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Mesenchymal chondrosarcoma; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 14.8 years (5,391 days).
Specimen 0DP48B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c7848b4-643d-40d7-8062-789bb224d486.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP46V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b88ee7cf-c96e-4d5a-8f68-26b071dcfc74

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Frame Shift Ins 1, 3'UTR 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHRNA4 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 64/1060 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201841018; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- SRGAP3 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 38/796 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1022202474, COSV64540978; called by muse, mutect2
- TCTN3 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 390/1408 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs200290528; called by muse, mutect2, varscan2
- USH2A | c.7378C>T p.R2460C | Missense Mutation (SNP) | VAF 388/1736 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs866943133, COSV56322035; called by muse, mutect2, varscan2
- ATP2B1 | c.3376A>C p.S1126R | Missense Mutation (SNP) | VAF 84/1284 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.491); called by muse, mutect2
- B4GALNT1 | c.1330G>C p.D444H | Missense Mutation (SNP) | VAF 102/390 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- COG2 | c.380dup p.M128Dfs*14 | Frame Shift Ins (INS) | VAF 343/1420 reads (24%) | called by mutect2, varscan2
- FCGRT | c.245G>A p.W82* | Nonsense Mutation (SNP) | VAF 116/494 reads (23%) | called by muse, mutect2, varscan2
- SLC25A16 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 195/884 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ANPEP | c.2769G>A p.K923= | Silent (SNP) | VAF 133/745 reads (18%) | called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 50/1448 reads (3%) | called by muse, mutect2
